Somatic mutation profile of tumor specimen HCM-BROD-0579-C16-06A (aliquot HCM-BROD-0579-C16-06A-11D-A85K-36) from HCMI case HCM-BROD-0579-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; Age at diagnosis: 36.9 years (13,485 days).
Specimen HCM-BROD-0579-C16-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 862d1802-46a2-41a5-b9d8-c4ca67692159.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0579-C16-10A (Blood Derived Normal), aliquot HCM-BROD-0579-C16-10A-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea068e67-4774-4fa2-ac97-51a27fb81076

The open-access MAF lists 131 somatic variants for this specimen: 95 protein-altering or splice-affecting, 33 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 33, Frame Shift Del 4, Frame Shift Ins 4, Splice Region 2, Nonsense Mutation 2, In Frame Del 2, RNA 1, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PCSK1 | c.920C>T p.S307L | Missense Mutation (SNP) | VAF 168/494 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs137852824, CM074404; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 196/348 reads (56%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ARHGAP28 | c.1912G>A p.V638M (on ENST00000383472 / NM_001366230.1; = p.V479M on NM_001010000.3) | Missense Mutation (SNP) | VAF 104/337 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV51641653; called by muse, mutect2, varscan2
- ARID5B | c.3026C>T p.A1009V | Missense Mutation (SNP) | VAF 167/570 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.491); catalogued as rs145564601, COSV54415348; called by muse, mutect2, varscan2
- ATP10A | c.1507C>T p.R503W | Missense Mutation (SNP) | VAF 199/616 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.052); catalogued as rs759620725, COSV63516659; called by muse, mutect2, varscan2
- B4GALT2 | c.1051C>T p.R351W | Missense Mutation (SNP) | VAF 94/446 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs1312790665, COSV100530561; called by muse, mutect2, varscan2
- CCDC102B | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 57/235 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs368864406; called by muse, mutect2, varscan2
- CDH8 | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 66/400 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.99); catalogued as COSV54872322; called by muse, mutect2, varscan2
- CHL1 | c.1043G>A p.G348D (on ENST00000397491 / NM_001253387.1; = p.G364D on NM_006614.4) | Missense Mutation (SNP) | VAF 42/232 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.134); catalogued as COSV99062447; called by muse, mutect2, varscan2
- CILP2 | c.2086G>A p.G696S | Missense Mutation (SNP) | VAF 99/456 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as rs780018968; called by muse, mutect2, varscan2
- CLCN2 | c.1882G>A p.E628K | Missense Mutation (SNP) | VAF 70/359 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as rs758247450, COSV99658487; called by muse, mutect2, varscan2
- CLSTN2 | c.2830G>C p.A944P | Missense Mutation (SNP) | VAF 74/332 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.059); catalogued as COSV101515847; called by muse, varscan2
- CRIM1 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 74/441 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as rs560635455, COSV99752611; called by muse, mutect2, varscan2
- CSMD1 | c.9487G>A p.A3163T (on ENST00000520002; = p.A3162T on NM_033225.6) | Missense Mutation (SNP) | VAF 112/220 reads (51%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as rs747067226, COSV59284416; called by muse, mutect2, varscan2
- CXCR4 | c.529G>A p.V177I | Missense Mutation (SNP) | VAF 174/420 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as rs767830104; called by muse, mutect2, varscan2
- CYP19A1 | c.514C>A p.L172M | Missense Mutation (SNP) | VAF 155/464 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); catalogued as COSV99547865; called by muse, mutect2, varscan2
- CYP4F22 | c.1379G>A p.R460H | Missense Mutation (SNP) | VAF 73/376 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV54111856; called by muse, mutect2, varscan2
- DMAC2 | c.461C>T p.S154L | Missense Mutation (SNP) | VAF 135/398 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.017); catalogued as rs782251451; called by muse, mutect2, varscan2
- DUOXA1 | c.614A>G p.Y205C | Missense Mutation (SNP) | VAF 54/511 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs988035611; called by muse, mutect2, varscan2
- EPB41L3 | c.2510C>T p.T837M | Missense Mutation (SNP) | VAF 116/321 reads (36%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.097); catalogued as rs143141379; called by muse, mutect2, varscan2
- FAM50A | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 131/469 reads (28%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.947); catalogued as rs370055697; called by muse, mutect2, varscan2
- FSHR | c.1973C>T p.T658I | Missense Mutation (SNP) | VAF 172/346 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.073); catalogued as rs148626637; called by muse, mutect2, varscan2
- FTSJ1 | c.529G>A p.V177M | Missense Mutation (SNP) | VAF 201/516 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs76994219, COSV99191451; called by muse, mutect2, varscan2
- GAREM1 | c.1673G>A p.R558Q | Missense Mutation (SNP) | VAF 153/544 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.033); catalogued as rs867526130; called by muse, mutect2, varscan2
- GNPDA2 | c.126G>A p.G42= | Splice Region (SNP) | VAF 13/113 reads (12%) | catalogued as rs1230830889; called by muse, mutect2, varscan2
- GOPC | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 52/290 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs754533147, COSV50000107; called by muse, mutect2, varscan2
- GPATCH8 | c.2905C>T p.R969* | Nonsense Mutation (SNP) | VAF 125/465 reads (27%) | catalogued as COSV100132787; called by muse, mutect2, varscan2
- LHFPL3 | c.346T>G p.F116V | Missense Mutation (SNP) | VAF 104/923 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV67813228; called by muse, mutect2, varscan2
- LILRB2 | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 224/594 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); catalogued as rs754528432, COSV58744319; called by muse, mutect2, varscan2
- LPO | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 101/460 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757850644, COSV51860612, COSV99229266; called by muse, mutect2, varscan2
- LRFN5 | c.706A>C p.S236R | Missense Mutation (SNP) | VAF 85/406 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1244908019, COSV53247525, COSV53257646; called by muse, mutect2, varscan2
- LRP4 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 153/426 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as rs1219866663, COSV101066959; called by muse, mutect2, varscan2
- MAGEB10 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 175/530 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV63312963; called by muse, mutect2, varscan2
- MAP3K15 | c.2966G>A p.R989Q | Missense Mutation (SNP) | VAF 119/370 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0.009); catalogued as rs370633600, COSV58838431; called by muse, mutect2, varscan2
- MMP16 | c.1162T>G p.L388V | Missense Mutation (SNP) | VAF 148/563 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54175920, COSV54189671, COSV99691040; called by muse, mutect2, varscan2
- NFASC | c.3018C>T p.S1006= | Splice Region (SNP) | VAF 110/284 reads (39%) | catalogued as rs866537431; called by muse, mutect2, varscan2
- NOX4 | c.461T>G p.L154R | Missense Mutation (SNP) | VAF 29/257 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); catalogued as rs1245898497, COSV54455974; called by muse, mutect2, varscan2
- NPAP1 | c.799G>A p.V267I | Missense Mutation (SNP) | VAF 115/444 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs776643326, COSV100275102, COSV61508889; called by muse, mutect2, varscan2
- PCDH8 | c.934G>A p.V312M | Missense Mutation (SNP) | VAF 118/723 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100131251; called by muse, mutect2, varscan2
- PCDHA7 | c.1823C>T p.S608L | Missense Mutation (SNP) | VAF 139/459 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.909); catalogued as COSV65342734; called by muse, mutect2, varscan2
- PITPNM1 | c.3515C>T p.A1172V | Missense Mutation (SNP) | VAF 159/504 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.314); catalogued as rs139473273; called by muse, mutect2, varscan2
- PRPS2 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 192/525 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV66126581; called by muse, mutect2, varscan2
- RND2 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 45/252 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.605); catalogued as rs183683037; called by muse, mutect2, varscan2
- RNF213 | c.9030G>T p.E3010D | Missense Mutation (SNP) | VAF 65/410 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.067); catalogued as rs192751125; called by muse, mutect2, varscan2
- SIK3 | c.1160G>A p.R387H (on ENST00000445177 / NM_001366686.2; = p.R393H on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 228/565 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs566690604, COSV52608905, COSV52625598; called by muse, mutect2, varscan2
- SMC2 | c.1760C>T p.A587V | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.082); catalogued as rs1465589429; called by muse, mutect2, varscan2
- SNTG1 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 124/539 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); catalogued as COSV52436233; called by muse, mutect2, varscan2
- SOX10 | c.826G>A p.V276M | Missense Mutation (SNP) | VAF 92/434 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.501); catalogued as rs766175657; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPATA31E1 | c.3350C>T p.P1117L | Missense Mutation (SNP) | VAF 75/505 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs372694780, COSV57790718, COSV57794674; called by muse, mutect2, varscan2
- SRRM2 | c.4565C>T p.S1522L | Missense Mutation (SNP) | VAF 88/582 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs1466235721; called by muse, mutect2, varscan2
- TANC1 | c.5134G>A p.G1712S | Missense Mutation (SNP) | VAF 80/424 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as rs767158516; called by muse, mutect2, varscan2
- TENM4 | c.2078G>A p.R693K | Missense Mutation (SNP) | VAF 94/538 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.054); catalogued as rs766879511; called by muse, mutect2, varscan2
- TMPRSS6 | c.943G>A p.V315M | Missense Mutation (SNP) | VAF 170/420 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs188371820, COSV60982929; called by muse, mutect2, varscan2
- VPS52 | c.538G>T p.A180S | Missense Mutation (SNP) | VAF 76/424 reads (18%) | SIFT tolerated (0.74); PolyPhen benign (0.029); catalogued as COSV71403611; called by muse, mutect2, varscan2
- XPA | c.734A>T p.E245V | Missense Mutation (SNP) | VAF 187/423 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1213747369; called by muse, mutect2, varscan2
- ZNF469 | c.9562G>A p.G3188R (on ENST00000437464; = p.G3216R on NM_001367624.2) | Missense Mutation (SNP) | VAF 118/745 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.027); catalogued as rs754615656; called by muse, mutect2, varscan2
- ZSCAN1 | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 226/558 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs200190736, COSV56607542; called by muse, mutect2, varscan2
- ACAP2 | c.1856T>G p.L619R | Missense Mutation (SNP) | VAF 129/331 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ADAMTS19 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 96/641 reads (15%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- APBA3 | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 95/463 reads (21%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1C | c.2809G>T p.D937Y | Missense Mutation (SNP) | VAF 47/316 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- CLEC17A | c.1130C>A p.S377Y | Missense Mutation (SNP) | VAF 68/296 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.543); called by muse, mutect2
- CTC1 | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 54/254 reads (21%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- CTNNB1 | c.1553C>A p.A518D | Missense Mutation (SNP) | VAF 60/242 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- DLG2 | c.392A>C p.K131T | Missense Mutation (SNP) | VAF 116/334 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- DNAH1 | c.4445C>T p.S1482F | Missense Mutation (SNP) | VAF 65/273 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- FGB | c.254T>G p.V85G | Missense Mutation (SNP) | VAF 169/367 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- FGF5 | c.292G>A p.G98S | Missense Mutation (SNP) | VAF 62/403 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FMN2 | c.2570C>T p.S857F | Missense Mutation (SNP) | VAF 168/429 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- IFNA10 | c.567T>A p.D189E | Missense Mutation (SNP) | VAF 44/248 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, varscan2
- IL2RB | c.1322dup p.S442Kfs*11 | Frame Shift Ins (INS) | VAF 74/428 reads (17%) | called by mutect2, varscan2
- JPH4 | c.148C>G p.L50V | Missense Mutation (SNP) | VAF 144/663 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- LINS1 | c.520dup p.C174Lfs*7 | Frame Shift Ins (INS) | VAF 41/227 reads (18%) | called by mutect2, pindel, varscan2
- LRBA | c.6537_6540del p.P2181Vfs*18 | Frame Shift Del (DEL) | VAF 32/166 reads (19%) | called by mutect2, pindel, varscan2
- MCM3AP | c.3980_3997del p.H1327_L1332del | In Frame Del (DEL) | VAF 41/283 reads (14%) | called by mutect2, pindel, varscan2
- MSN | c.452A>C p.K151T | Missense Mutation (SNP) | VAF 83/312 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- MYH2 | c.3982_3984del p.E1328del | In Frame Del (DEL) | VAF 35/152 reads (23%) | called by pindel, varscan2
- MYO9A | c.3997C>A p.L1333I | Missense Mutation (SNP) | VAF 35/311 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- NOL8 | c.1897G>A p.A633T | Missense Mutation (SNP) | VAF 124/312 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OR6N2 | c.452G>T p.C151F | Missense Mutation (SNP) | VAF 60/340 reads (18%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- PIGR | c.1035_1038del p.F345Lfs*14 | Frame Shift Del (DEL) | VAF 112/327 reads (34%) | called by mutect2, pindel, varscan2
- PLA2G4D | c.2233G>T p.V745F | Missense Mutation (SNP) | VAF 84/267 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- PREPL | c.1078_1079del p.V360Sfs*12 | Frame Shift Del (DEL) | VAF 52/454 reads (11%) | called by pindel, varscan2
- PRR13 | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 59/366 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- RNF144A | c.840C>A p.C280* | Nonsense Mutation (SNP) | VAF 51/435 reads (12%) | called by muse, mutect2, varscan2
- SLC27A6 | c.1191G>T p.K397N | Missense Mutation (SNP) | VAF 52/288 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, varscan2
- SLC2A13 | c.1033A>G p.M345V | Missense Mutation (SNP) | VAF 99/1376 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); called by muse, mutect2
- SOX9 | c.1294dup p.Y432Lfs*146 | Frame Shift Ins (INS) | VAF 241/765 reads (32%) | called by mutect2, pindel, varscan2
- SOX9 | c.1507dup p.Y503Lfs*75 | Frame Shift Ins (INS) | VAF 164/562 reads (29%) | called by mutect2, pindel, varscan2
- STRAP | c.257G>T p.W86L | Missense Mutation (SNP) | VAF 45/215 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TSPAN3 | c.664_667delinsGAT p.I222Dfs*34 | Frame Shift Del (DEL) | VAF 137/387 reads (35%) | called by pindel, varscan2*
- USP34 | c.5483A>T p.K1828M | Missense Mutation (SNP) | VAF 95/580 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- WDFY3 | c.10519C>G p.Q3507E | Missense Mutation (SNP) | VAF 58/250 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by mutect2, varscan2
- ZNF544 | c.1932C>A p.S644R | Missense Mutation (SNP) | VAF 92/410 reads (22%) | SIFT tolerated (0.93); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- ZNF83 | c.46C>A p.Q16K | Missense Mutation (SNP) | VAF 56/297 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ADRB1 | c.882C>T p.A294= | Silent (SNP) | VAF 51/182 reads (28%) | called by muse, mutect2, varscan2
- ATP2B2 | c.1725C>T p.P575= (on ENST00000352432; = p.P541= on NM_001683.5) | Silent (SNP) | VAF 113/405 reads (28%) | catalogued as rs750508666; called by muse, mutect2, varscan2
- CCIN | c.1737G>A p.K579= | Silent (SNP) | VAF 121/289 reads (42%) | called by muse, mutect2, varscan2
- CDH1 | c.1677C>T p.S559= | Silent (SNP) | VAF 185/307 reads (60%) | called by muse, mutect2, varscan2
- CEACAM5 | c.432G>A p.L144= | Silent (SNP) | VAF 33/404 reads (8%) | catalogued as rs782062922; called by muse, mutect2
- CHRNB3 | c.375C>T p.F125= | Silent (SNP) | VAF 106/214 reads (50%) | catalogued as rs1053084474, COSV51494803, COSV99251439; called by muse, mutect2, varscan2
- CRHBP | c.213C>T p.T71= | Silent (SNP) | VAF 157/418 reads (38%) | called by muse, mutect2, varscan2
- DMRT2 | c.192C>T p.D64= | Silent (SNP) | VAF 248/628 reads (39%) | catalogued as rs749640485; called by muse, varscan2
- GATA1 | c.240G>A p.L80= | Silent (SNP) | VAF 128/438 reads (29%) | called by muse, mutect2, varscan2
- GRIA2 | c.1002A>C p.P334= | Silent (SNP) | VAF 65/317 reads (21%) | catalogued as COSV52393268; called by muse, mutect2, varscan2
- IFT140 | c.1395G>A p.A465= | Silent (SNP) | VAF 134/494 reads (27%) | catalogued as rs949232096; called by muse, mutect2, varscan2
- KCNQ2 | c.867C>T p.N289= | Silent (SNP) | VAF 191/573 reads (33%) | catalogued as rs749934609, COSV60434788; ClinVar: likely benign; called by muse, mutect2, varscan2
- LAMC3 | c.2094G>T p.G698= | Silent (SNP) | VAF 99/441 reads (22%) | called by muse, mutect2, varscan2
- LMNB1 | c.1140C>G p.L380= | Silent (SNP) | VAF 76/293 reads (26%) | catalogued as COSV54396530; called by muse, mutect2, varscan2
- LRRC15 | c.36C>A p.G12= | Silent (SNP) | VAF 72/349 reads (21%) | called by muse, mutect2, varscan2
- MGAT3 | c.183C>T p.S61= | Silent (SNP) | VAF 254/564 reads (45%) | catalogued as rs776996531, COSV57868898; called by muse, mutect2, varscan2
- NACC1 | c.774G>A p.T258= | Silent (SNP) | VAF 239/559 reads (43%) | catalogued as rs755984117; called by muse, mutect2, varscan2
- PNPLA6 | c.471G>A p.T157= (on ENST00000414982 / NM_001166111.2; = p.T109= on NM_006702.5) | Silent (SNP) | VAF 107/286 reads (37%) | catalogued as rs766433753; called by muse, mutect2, varscan2
- PRR32 | c.759G>T p.P253= | Silent (SNP) | VAF 245/730 reads (34%) | catalogued as COSV100947902, COSV64420509; called by muse, mutect2, varscan2
- PTPRM | c.174T>A p.T58= | Silent (SNP) | VAF 62/260 reads (24%) | called by muse, mutect2, varscan2
- RECQL4 | c.858G>A p.S286= | Silent (SNP) | VAF 241/858 reads (28%) | called by muse, mutect2, varscan2
- RNF169 | c.138G>A p.S46= | Silent (SNP) | VAF 225/650 reads (35%) | catalogued as rs1474085626; called by muse, mutect2, varscan2
- RYR1 | c.7047C>T p.N2349= | Silent (SNP) | VAF 100/501 reads (20%) | catalogued as rs149295336; called by muse, mutect2, varscan2
- SLC16A6 | c.555C>T p.F185= | Silent (SNP) | VAF 111/398 reads (28%) | catalogued as rs141718604; called by muse, mutect2, varscan2
- TCF15 | c.183C>T p.G61= | Silent (SNP) | VAF 61/139 reads (44%) | called by muse, mutect2, varscan2
- TRAM2 | c.129C>T p.A43= | Silent (SNP) | VAF 32/241 reads (13%) | called by muse, mutect2, varscan2
- TRMT10B | c.897G>A p.L299= | Silent (SNP) | VAF 67/287 reads (23%) | catalogued as rs1372408190, COSV53050286; called by muse, mutect2, varscan2
- TSHZ1 | c.1710G>A p.A570= (on ENST00000580243 / NM_001308210.2; = p.A525= on NM_005786.6) | Silent (SNP) | VAF 165/442 reads (37%) | catalogued as rs763038442; called by muse, mutect2, varscan2
- VSIG10 | c.1053C>T p.P351= | Silent (SNP) | VAF 47/529 reads (9%) | catalogued as rs569997181; called by muse, mutect2
- WDR86 | c.810G>A p.T270= | Silent (SNP) | VAF 205/495 reads (41%) | catalogued as rs369021299; called by muse, mutect2, varscan2
- ZNF207 | c.519A>C p.G173= | Silent (SNP) | VAF 84/348 reads (24%) | called by muse, mutect2, varscan2
- ZNF729 | c.3201G>A p.K1067= | Silent (SNP) | VAF 153/379 reads (40%) | catalogued as rs779373036; called by muse, mutect2, varscan2
- ZPR1 | c.81C>A p.A27= | Silent (SNP) | VAF 100/730 reads (14%) | catalogued as rs1333125492; called by muse, mutect2, varscan2
- C4orf50 | chr4:5990253 G>T | 5'Flank (SNP) | VAF 66/349 reads (19%) | called by muse, mutect2, varscan2
- IQCK | c.802+36A>T | Intron (SNP) | VAF 135/425 reads (32%) | called by muse, mutect2, varscan2
- NMRAL2P | n.212C>T | RNA (SNP) | VAF 169/415 reads (41%) | called by muse, mutect2, varscan2
